Surgical pathology report (de-identified scan), TCGA case TCGA-AG-4021, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-4021-01A (Primary Tumor).

[REDACTED]
Diagnosis:

This concerns in 1) liver metastases of a poorly differentiated adenocarcinoma of the colon, in II) further sections of the poorly differentiated adenocarcinoma of the colon described (G3), and in III) an invasive adenocarcinoma of the colon in the rectal position, poorly differentiated (G3), with extensive lymph vessel dilatation (L1, V1) and lymph node conglomerate metastases (over five - pN2).

Tumor classification:

ICDO-DA M-8140/3,

G3,

pT3, pN2
[REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file 95804275-373e-47a2-9056-ae602c948f02 (TCGA-AG-4021.3675BFD7-89CB-4612-B5E6-E900E8D2FC13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).